Somatic mutation profile of tumor specimen 0DVZ1J from CCDI case PBCNLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,734 days).
Specimen 0DVZ1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb34da9-eb11-49db-b22c-5319ed1b9766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b4405bc-902a-4dfe-85ef-1cb69cd462a1

The open-access MAF lists 98 somatic variants for this specimen: 78 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 13, Intron 7, Nonsense Mutation 5, Splice Site 4, Splice Region 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGCE | c.397C>T p.R133* (on ENST00000647096; = p.R97* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 73/452 reads (16%) | catalogued as rs121908489, CM012802, COSV56019205; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as CM1210653, COSV66069431; called by muse, mutect2, varscan2
- ADAMTS4 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 134/408 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs746614498; called by muse, mutect2, varscan2
- ADORA3 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53985023; called by muse, mutect2
- CLCA1 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs781182283; called by muse, mutect2, varscan2
- CMC4 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.334); catalogued as COSV100749876; called by muse, mutect2
- COBL | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs749249733, COSV54344223; called by muse, mutect2
- DLX1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 155/560 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100250078; called by muse, mutect2, varscan2
- HAND1 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 43/442 reads (10%) | catalogued as COSV50563686; called by muse, mutect2
- HAP1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 112/415 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782707816; called by muse, mutect2, varscan2
- IGSF9 | c.2283C>A p.N761K (on ENST00000368094 / NM_001135050.2; = p.N745K on NM_020789.4) | Missense Mutation (SNP) | VAF 50/603 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1171776552; called by muse, mutect2
- LCE1A | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 139/574 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.994); catalogued as COSV58727469; called by muse, mutect2, varscan2
- LCE2B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 163/645 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs759523297, COSV100909340, COSV64228104; called by muse, mutect2, varscan2
- MCM7 | c.987G>A p.E329= | Splice Region (SNP) | VAF 59/343 reads (17%) | catalogued as COSV57997871; called by muse, mutect2, varscan2
- MUC16 | c.39264C>G p.N13088K | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV66694248; called by muse, mutect2
- MUC16 | c.9317C>A p.T3106K | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs1039390427; called by muse, mutect2, varscan2
- PIGN | c.1669G>T p.V557L | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1187980465; called by muse, mutect2
- POU3F3 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1307492164, COSV63722429; called by muse, mutect2
- RGPD8 | c.2802G>C p.K934N | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV56898338; called by muse, mutect2
- RPAP3 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV50041337; called by muse, mutect2, varscan2
- SEMA3D | c.1926A>T p.R642S | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs373922127; called by muse, mutect2, varscan2
- SLAMF6 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 165/579 reads (28%) | catalogued as COSV63586341, COSV63588277; called by muse, mutect2, varscan2
- SLC22A8 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs769079351; called by mutect2, varscan2
- SLC4A10 | c.1709G>A p.G570E (on ENST00000446997 / NM_001354461.2; = p.G540E on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55764349; called by muse, mutect2, varscan2
- SMIM3 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 37/459 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs780575873; called by muse, mutect2
- TEX13C | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1420234236; called by muse, mutect2
- TLK1 | c.813A>G p.I271M | Missense Mutation (SNP) | VAF 35/401 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); catalogued as rs1383741085; called by muse, mutect2
- TNFRSF11B | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52069378, COSV52074140; called by muse, mutect2
- ZNF697 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 21/388 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs752725495; called by muse, mutect2
- A3GALT2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 155/554 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA10 | c.4490T>G p.F1497C | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ALAS1 | c.1204C>G p.H402D | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- APOB | c.11360C>T p.P3787L | Missense Mutation (SNP) | VAF 106/455 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMCX5 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CAP2 | c.447T>C p.S149= | Splice Region (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- CFAP46 | c.4511+4G>T | Splice Region (SNP) | VAF 21/487 reads (4%) | called by muse, mutect2
- CMC4 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- COL27A1 | c.1807dup p.R603Pfs*90 | Frame Shift Ins (INS) | VAF 88/278 reads (32%) | called by mutect2, pindel, varscan2
- DCHS2 | n.5994-1G>C | Splice Site (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- DCHS2 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 134/613 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DDX17 | c.1215-1G>A p.X405_splice | Splice Site (SNP) | VAF 78/370 reads (21%) | called by muse, mutect2, varscan2
- DDX43 | c.1703T>G p.I568S | Missense Mutation (SNP) | VAF 50/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- DGKD | c.267+1G>C p.X89_splice (on ENST00000264057 / NM_152879.3; = p.X45_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/579 reads (6%) | called by muse, mutect2
- DNAJA3 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ESPNL | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- F2RL3 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- FILIP1 | c.764A>C p.Q255P | Missense Mutation (SNP) | VAF 50/715 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ICAM5 | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.191); called by muse, mutect2
- INTS9 | c.1752G>C p.L584F | Missense Mutation (SNP) | VAF 16/461 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.288); called by muse, mutect2
- ITPRID1 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2
- KCNG2 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 138/686 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KCNH4 | c.2768G>C p.W923S | Missense Mutation (SNP) | VAF 134/416 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL5 | c.2040-2A>C p.X680_splice | Splice Site (SNP) | VAF 72/272 reads (26%) | called by muse, mutect2, varscan2
- KRT77 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MFN2 | c.2015A>T p.K672M | Missense Mutation (SNP) | VAF 109/456 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MNX1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 204/1167 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NACAD | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NAV3 | c.2840C>G p.P947R | Missense Mutation (SNP) | VAF 20/395 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- NEK5 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOTCH2 | c.3632G>T p.C1211F | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR4A2 | c.1273C>A p.P425T | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRCAM | c.142A>T p.I48F (on ENST00000379028 / NM_001371124.1; = p.I42F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- OTX1 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.53); called by muse, mutect2
- PPDPFL | c.57G>A p.K19= | Splice Region (SNP) | VAF 65/165 reads (39%) | called by muse, mutect2, varscan2
- PRMT6 | c.141C>G p.Y47* | Nonsense Mutation (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- RNF145 | c.1346A>T p.D449V (on ENST00000424310 / NM_001199383.2; = p.D477V on NM_144726.2) | Missense Mutation (SNP) | VAF 104/418 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SERPINB2 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 124/548 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SHANK1 | c.5125G>A p.G1709R | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SIRT7 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 37/533 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SLC24A1 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 11/329 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); called by muse, mutect2
- SLIT3 | c.1999T>A p.C667S | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNM | c.3503G>C p.S1168T | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UBE3C | c.2753C>G p.A918G | Missense Mutation (SNP) | VAF 109/685 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UHRF1BP1 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VASH2 | c.913C>G p.Q305E (on ENST00000517399 / NM_001301056.2; = p.Q261E on NM_024749.5) | Missense Mutation (SNP) | VAF 42/584 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2
- ZNF121 | c.463T>G p.Y155D | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF160 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 37/636 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- AGPAT1 | c.228C>T p.I76= | Silent (SNP) | VAF 34/650 reads (5%) | called by muse, mutect2
- ARMCX2 | c.1176T>C p.L392= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- CDSN | c.534C>G p.T178= | Silent (SNP) | VAF 32/495 reads (6%) | catalogued as COSV99457019; called by muse, mutect2
- CEACAM20 | c.429C>A p.A143= | Silent (SNP) | VAF 64/410 reads (16%) | catalogued as COSV57601302; called by muse, mutect2, varscan2
- DYM | c.1689C>G p.L563= | Silent (SNP) | VAF 30/1194 reads (3%) | called by muse, mutect2
- FCMR | c.981T>G p.A327= | Silent (SNP) | VAF 29/386 reads (8%) | called by muse, mutect2
- HSD11B1L | c.553C>T p.L185= | Silent (SNP) | VAF 183/791 reads (23%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1794T>C p.H598= | Silent (SNP) | VAF 28/416 reads (7%) | called by muse, mutect2
- MAGED2 | c.318C>A p.T106= | Silent (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- RAB31 | c.375T>C p.D125= | Silent (SNP) | VAF 31/674 reads (5%) | called by muse, mutect2
- THSD4 | c.1878A>G p.T626= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as rs774150611; called by muse, mutect2
- TIAL1 | c.306G>C p.G102= | Silent (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- TMEM30A | c.1020A>G p.G340= | Silent (SNP) | VAF 12/405 reads (3%) | called by muse, mutect2
- CD74 | c.378+91C>A | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- GTPBP2 | c.705+73G>T | Intron (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- IKBKE | c.1836-60G>C | Intron (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- JADE2 | c.1553-1608G>T | Intron (SNP) | VAF 73/271 reads (27%) | catalogued as rs1032739567; called by muse, mutect2, varscan2
- PSMD8 | c.915+15G>A | Intron (SNP) | VAF 12/227 reads (5%) | catalogued as rs1473368881; called by muse, mutect2
- ROPN1B | c.396+67C>G | Intron (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- RXRB | c.1349-29T>C | Intron (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
